Somatic mutation profile of tumor specimen MMRF_2665_1_BM_CD138pos (aliquot MMRF_2665_1_BM_CD138pos_T1_KHS5U_L13782) from MMRF case MMRF_2665, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,898 days).
Specimen MMRF_2665_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0597ecb4-f05a-4f7c-b50f-5d10a7e6b870.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2665_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2665_1_PB_WBC_C3_KHS5U_L13783; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d61e3998-69ee-4a49-bfad-227375e303fa

The open-access MAF lists 78 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 20, Silent 14, Intron 5, 5'UTR 4, 5'Flank 2, RNA 2, 3'Flank 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 50/160 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CGNL1 | c.3013C>A p.L1005M | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs376703525, COSV99849456; called by muse, mutect2, varscan2
- CSMD1 | c.3206C>T p.T1069M (on ENST00000520002; = p.T1068M on NM_033225.6) | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.475); catalogued as rs373654565; called by muse, mutect2, varscan2
- DSCAML1 | c.991C>T p.R331C (on ENST00000321322; = p.R271C on NM_020693.4) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261825926, COSV58392509; called by muse, mutect2, varscan2
- FLT1 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1433837792; called by muse, mutect2, varscan2
- IGHV1-3 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT tolerated (0.19); PolyPhen benign (0.075); catalogued as rs782769944; called by muse, varscan2
- INTS13 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs761072271; called by muse, mutect2, varscan2
- KCNA4 | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1361165616, COSV100069306; called by muse, mutect2, varscan2
- MRGPRE | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs936953413; called by muse, mutect2, varscan2
- MYH8 | c.5699G>A p.R1900H | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770787118, COSV101238060; called by muse, mutect2, varscan2
- SCN10A | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs375926577, COSV101479488; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRABD2B | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.349); catalogued as rs1324799083; called by muse, mutect2
- ANKRD33B | c.80del p.G27Afs*83 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel, varscan2
- ARHGAP24 | c.2055T>G p.D685E (on ENST00000395184 / NM_001025616.3; = p.D592E on NM_031305.3) | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf97 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CAPRIN2 | c.2324A>G p.Y775C | Missense Mutation (SNP) | VAF 79/160 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL15A1 | c.3275C>T p.P1092L | Missense Mutation (SNP) | VAF 79/293 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- EMILIN2 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GDF2 | c.273C>G p.D91E | Missense Mutation (SNP) | VAF 106/243 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HNRNPA1 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HS3ST3A1 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.02); called by muse, mutect2
- IGHV3-30 | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); called by muse, varscan2
- LUC7L2 | c.517dup p.Y173Lfs*19 | Frame Shift Ins (INS) | VAF 48/141 reads (34%) | called by mutect2, pindel, varscan2
- NWD1 | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHOC1 | c.513T>A p.N171K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.84); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SI | c.5381A>C p.N1794T | Missense Mutation (SNP) | VAF 188/344 reads (55%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- SSX2IP | c.1141C>G p.Q381E | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM2 | c.217G>A p.G73R (on ENST00000437508; = p.G100R on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 142/331 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TXNRD1 | c.335C>T p.S112L (on ENST00000525566 / NM_001093771.3; = p.S14L on NM_003330.4) | Missense Mutation (SNP) | VAF 73/190 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- XRN1 | c.1608T>A p.N536K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BLK | c.327C>T p.P109= | Silent (SNP) | VAF 114/286 reads (40%) | catalogued as rs745743574; called by muse, varscan2
- IRAG1 | c.2580A>C p.A860= | Silent (SNP) | VAF 96/357 reads (27%) | called by muse, varscan2
- LIG4 | c.1719C>T p.G573= | Silent (SNP) | VAF 154/404 reads (38%) | called by muse, mutect2, varscan2
- LRIT2 | c.459G>T p.L153= | Silent (SNP) | VAF 78/176 reads (44%) | called by muse, varscan2
- NR5A1 | c.435T>C p.H145= | Silent (SNP) | VAF 28/138 reads (20%) | called by muse, mutect2, varscan2
- NRCAM | c.1155T>C p.N385= (on ENST00000379028 / NM_001371124.1; = p.N379= on NM_005010.4 and 21 other RefSeq transcripts) | Silent (SNP) | VAF 63/162 reads (39%) | called by muse, mutect2, varscan2
- OPLAH | c.513C>T p.A171= | Silent (SNP) | VAF 44/118 reads (37%) | catalogued as COSV70678577; called by muse, mutect2, varscan2
- PTPRT | c.3399T>C p.Y1133= | Silent (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- ROBO1 | c.3285C>A p.G1095= | Silent (SNP) | VAF 70/246 reads (28%) | called by muse, mutect2, varscan2
- SLC6A18 | c.258C>T p.S86= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs150474619; called by muse, mutect2, varscan2
- TBX6 | c.90C>T p.P30= | Silent (SNP) | VAF 46/100 reads (46%) | called by muse, mutect2, varscan2
- THEGL | c.18T>C p.F6= | Silent (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- XBP1 | c.156C>T p.S52= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as rs1242665723; called by muse, mutect2, varscan2
- ZCWPW2 | c.237T>G p.P79= | Silent (SNP) | VAF 120/203 reads (59%) | called by muse, mutect2, varscan2
- ABR | c.*1589T>C | 3'UTR (SNP) | VAF 78/274 reads (28%) | called by muse, mutect2, varscan2
- ADGRE1 | c.514+895C>T | Intron (SNP) | VAF 73/265 reads (28%) | catalogued as rs769165138; called by muse, mutect2, varscan2
- ALK | c.3516-369C>T | Intron (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- BCL7A | c.*364G>A | 3'UTR (SNP) | VAF 127/373 reads (34%) | catalogued as rs941801973; called by muse, mutect2, varscan2
- C11orf45 | c.*2141A>G | 3'UTR (SNP) | VAF 61/224 reads (27%) | called by muse, mutect2, varscan2
- CALB1 | c.*447_*450del | 3'UTR (DEL) | VAF 44/122 reads (36%) | catalogued as rs1325664640; called by mutect2, pindel, varscan2
- CEP57 | c.-90C>T | 5'UTR (SNP) | VAF 52/190 reads (27%) | catalogued as rs1325598768, COSV57688875; called by muse, mutect2, varscan2
- CNTNAP5 | c.*224G>A | 3'UTR (SNP) | VAF 78/175 reads (45%) | catalogued as rs1016263807; called by muse, mutect2, varscan2
- CYYR1 | c.*120G>A | 3'UTR (SNP) | VAF 47/105 reads (45%) | called by muse, mutect2, varscan2
- DOK3 | c.-118+16_-118+36del | Intron (DEL) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- EGFR | c.*585A>G | 3'UTR (SNP) | VAF 34/98 reads (35%) | called by muse, mutect2, varscan2
- EXOC7 | c.*1242G>A | 3'UTR (SNP) | VAF 38/106 reads (36%) | catalogued as rs536559451; called by muse, mutect2, varscan2
- FADS1 | c.*202C>G | 3'UTR (SNP) | VAF 50/223 reads (22%) | called by muse, varscan2
- FOXO6 | chr1:41382793 G>A | 3'Flank (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- GLE1 | c.*983C>G | 3'UTR (SNP) | VAF 22/74 reads (30%) | called by mutect2, varscan2
- HBE1 | c.-267+102596_-267+102597del | Intron (DEL) | VAF 69/311 reads (22%) | called by mutect2, pindel, varscan2
- KAZN | c.-399G>T | 5'UTR (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- KCNK13 | c.*461G>T | 3'UTR (SNP) | VAF 33/90 reads (37%) | called by muse, mutect2, varscan2
- KLF13 | c.*5173C>A | 3'UTR (SNP) | VAF 64/260 reads (25%) | called by muse, mutect2, varscan2
- LINC02872 | n.2573_2574del | RNA (DEL) | VAF 14/106 reads (13%) | called by pindel, varscan2
- LNPK | c.*490A>G | 3'UTR (SNP) | VAF 42/108 reads (39%) | catalogued as rs768221630; called by muse, mutect2, varscan2
- LVRN | c.-94G>C | 5'UTR (SNP) | VAF 47/139 reads (34%) | catalogued as rs1360630611; called by muse, mutect2, varscan2
- MECOM | c.-54-92G>T | Intron (SNP) | VAF 30/100 reads (30%) | called by muse, mutect2, varscan2
- MPV17L | c.*226A>G | 3'UTR (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- NHLH2 | chr1:115841985 A>T | 5'Flank (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2
- OR10V2P | n.456C>T | RNA (SNP) | VAF 88/346 reads (25%) | catalogued as rs772734547; called by muse, mutect2, varscan2
- PA2G4 | c.*391A>G | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- PLXDC1 | c.*3615A>G | 3'UTR (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- PSAPL1 | c.*1422C>T | 3'UTR (SNP) | VAF 46/117 reads (39%) | catalogued as rs780352023; called by muse, mutect2, varscan2
- RBM15B | c.*2639T>C | 3'UTR (SNP) | VAF 103/331 reads (31%) | catalogued as rs936707195; called by muse, mutect2, varscan2
- RTF2 | c.*420del | 3'UTR (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- RUNX1T1 | c.*1101T>A | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- SQSTM1 | c.-4C>T | 5'UTR (SNP) | VAF 36/117 reads (31%) | catalogued as rs920805837, COSV62435173, COSV62435295; called by muse, mutect2, varscan2
- TAF1B | chr2:9843446 C>T | 5'Flank (SNP) | VAF 52/118 reads (44%) | catalogued as rs543802289, COSV55158132; called by muse, varscan2
